Somatic mutation profile of tumor specimen TCGA-DA-A95W-06A (aliquot TCGA-DA-A95W-06A-11D-A372-08) from TCGA case TCGA-DA-A95W, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 52.3 years (19,105 days).
Specimen TCGA-DA-A95W-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8c11424-0764-4866-849a-fdb14b44e8cf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DA-A95W-10A (Blood Derived Normal), aliquot TCGA-DA-A95W-10A-01D-A375-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad72f3ac-02b0-489e-9102-f6ad53f635a7

The open-access MAF lists 182 somatic variants for this specimen: 129 protein-altering or splice-affecting, 47 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 119, Silent 47, Nonsense Mutation 5, RNA 4, Splice Site 2, Intron 2, Frame Shift Ins 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/91 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CACNA1A | c.5411C>T p.S1804L | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1064794261, CM1311258, COSV64192167; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LDLR | c.1576C>T p.P526S | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882106, CM100938, CM920460, COSV52942440; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC1 | c.2054C>T p.S685L | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60696151; called by muse, mutect2, varscan2
- ACACB | c.5711G>A p.G1904D | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58149061; called by muse, mutect2, varscan2
- ADAMTS13 | c.4038G>A p.M1346I | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV52472095; called by muse, mutect2, varscan2
- ADAMTS16 | c.3149C>T p.P1050L | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV57009862; called by muse, mutect2, varscan2
- AP5S1 | c.527A>G p.H176R | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as rs745659634, COSV55694802; called by muse, mutect2, varscan2
- AS3MT | c.1040T>G p.F347C | Missense Mutation (SNP) | VAF 20/29 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV54919450; called by muse, mutect2, varscan2
- ATP8B1 | c.3305C>T p.S1102L | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.113); catalogued as rs1277087294, COSV52178472, COSV52181140; called by muse, mutect2, varscan2
- B3GALNT1 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV57581446; called by muse, mutect2, varscan2
- CACNB4 | c.1447G>T p.D483Y | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV52405614; called by muse, mutect2, varscan2
- CAPN13 | c.1415G>A p.R472Q | Missense Mutation (SNP) | VAF 88/190 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.727); catalogued as rs762095086, COSV54431312; called by muse, mutect2, varscan2
- CATSPERD | c.2086C>T p.P696S | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58468007; called by muse, mutect2, varscan2
- CCDC77 | c.131C>T p.S44F | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs759355080, COSV53475781; called by muse, mutect2, varscan2
- CDYL | c.1640T>C p.V547A (on ENST00000328908 / NM_001368125.1; = p.V493A on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.548); catalogued as COSV59362265; called by muse, mutect2, varscan2
- CEPT1 | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV100853499; called by muse, mutect2, varscan2
- CFH | c.3202C>T p.P1068S | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as rs759231269, COSV66414663; called by muse, mutect2, varscan2
- CHGB | c.1433G>A p.G478E | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0.009); catalogued as COSV66762078; called by muse, mutect2, varscan2
- CHID1 | c.1083+1G>A p.X361_splice | Splice Site (SNP) | VAF 19/52 reads (37%) | catalogued as rs780419403, COSV60260971; called by muse, mutect2, varscan2
- CLCN1 | c.2422G>A p.E808K | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs866998861, COSV58375257; called by muse, mutect2, varscan2
- CLDN19 | c.223+1G>A p.X75_splice | Splice Site (SNP) | VAF 7/20 reads (35%) | catalogued as rs758302356, COSV99591723; called by muse, mutect2, varscan2
- CSMD3 | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 125/309 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs755471454, COSV52241436; called by muse, mutect2, varscan2
- DENND5A | c.3187G>A p.G1063R | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60238654; called by muse, mutect2, varscan2
- DNAH10 | c.11701C>T p.R3901W (on ENST00000409039; = p.R3840W on NM_207437.3) | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV68996714; called by muse, mutect2, varscan2
- DNAH11 | c.8657G>A p.G2886E | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV100180356; called by muse, mutect2, varscan2
- DNAH3 | c.3821G>A p.R1274Q | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs777984798, COSV54506633; called by muse, mutect2, varscan2
- ENAM | c.2294C>T p.S765F | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV68536812; called by muse, mutect2
- EPHA7 | c.1609G>A p.E537K | Missense Mutation (SNP) | VAF 34/44 reads (77%) | SIFT tolerated (0.09); PolyPhen benign (0.196); catalogued as rs1009626356, COSV65183025; called by muse, mutect2, varscan2
- FAM160B1 | c.1321C>T p.P441S | Missense Mutation (SNP) | VAF 50/70 reads (71%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.898); catalogued as COSV65090020; called by muse, mutect2, varscan2
- FAT4 | c.2609G>A p.G870E | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV101272952, COSV67902813; called by muse, mutect2, varscan2
- FRMD3 | c.1468G>A p.E490K | Missense Mutation (SNP) | VAF 57/124 reads (46%) | SIFT tolerated (0.54); PolyPhen benign (0.281); catalogued as COSV58464860; called by muse, mutect2, varscan2
- G6PC2 | c.803G>A p.G268D | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56373821; called by muse, mutect2, varscan2
- GAS8 | c.41_42del p.G14Dfs*62 | Frame Shift Del (DEL) | VAF 13/70 reads (19%) | catalogued as COSV51946663; called by mutect2, pindel, varscan2
- GBP4 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.057); catalogued as rs917812273, COSV63253488; called by muse, mutect2, varscan2
- GRIN2A | c.2971T>C p.S991P | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.8); catalogued as COSV58059634; called by muse, mutect2, varscan2
- GRM8 | c.1742C>T p.S581F | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV58807209, COSV58878853; called by muse, mutect2, varscan2
- GSTCD | c.1867C>T p.P623S (on ENST00000360505 / NM_001031720.3; = p.P536S on NM_024751.3) | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64736203; called by muse, mutect2, varscan2
- GSTZ1 | c.331C>T p.Q111* | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | catalogued as COSV53622771, COSV53624778; called by muse, mutect2, varscan2
- HAUS1 | c.409A>C p.K137Q | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV56364349; called by muse, mutect2, varscan2
- HELZ | c.4330C>T p.P1444S | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.01); catalogued as rs1260235924, COSV62381406; called by muse, mutect2, varscan2
- HLA-DQA2 | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs1194485476, COSV100890782, COSV100890817; called by muse, mutect2, varscan2
- HSD3B2 | c.718C>T p.R240W | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as rs370603955, COSV65593113; called by muse, mutect2, varscan2
- ICE1 | c.4352C>T p.S1451F | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as COSV99665474; called by muse, mutect2, varscan2
- IGLC7 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as rs1158582269; called by muse, mutect2, varscan2
- IGSF9B | c.3244C>T p.P1082S | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.043); catalogued as COSV100318250; called by muse, mutect2, varscan2
- KHDRBS2 | c.310A>G p.K104E | Missense Mutation (SNP) | VAF 50/64 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV55498194; called by muse, mutect2, varscan2
- KIAA1755 | c.869C>T p.P290L | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.045); catalogued as COSV54081765; called by muse, mutect2, varscan2
- KIF4B | c.3418G>A p.G1140S | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.014); catalogued as COSV101469186, COSV70531922; called by muse, mutect2, varscan2
- LILRB2 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 51/95 reads (54%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as rs145209585; called by muse, mutect2, varscan2
- LMTK3 | c.647G>A p.G216E | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99541063; called by muse, mutect2, varscan2
- LMTK3 | c.646G>A p.G216R | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54318078; called by muse, mutect2, varscan2
- LRP1B | c.11776A>T p.M3926L | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.651); catalogued as COSV67284486; called by muse, mutect2, varscan2
- MAGEC3 | c.115C>T p.Q39* | Nonsense Mutation (SNP) | VAF 54/64 reads (84%) | catalogued as rs866359573, COSV74217501; called by muse, mutect2, varscan2
- MAGI1 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 54/110 reads (49%) | SIFT tolerated (0.56); PolyPhen benign (0.441); catalogued as COSV58345969; called by muse, mutect2, varscan2
- MAST4 | c.2953G>C p.G985R (on ENST00000403625 / NM_001164664.2; = p.G796R on NM_015183.3) | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.044); catalogued as COSV55145723; called by muse, mutect2
- MCTP2 | c.315G>A p.W105* | Nonsense Mutation (SNP) | VAF 67/121 reads (55%) | catalogued as COSV59151631; called by muse, mutect2, varscan2
- MORC2 | c.296A>T p.Q99L (on ENST00000397641 / NM_001303256.3; = p.Q37L on NM_014941.3) | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53196184; called by muse, mutect2, varscan2
- MTUS2 | c.3094G>A p.A1032T | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV70924436; called by muse, mutect2, varscan2
- MUC16 | c.332G>A p.G111E | Missense Mutation (SNP) | VAF 50/97 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs1335513253, COSV67490584; called by muse, mutect2, varscan2
- MYO6 | c.728G>A p.R243K | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV64118250, COSV64121986; called by muse, mutect2, varscan2
- NCOR2 | c.1012C>T p.P338S | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62293701; called by muse, mutect2, varscan2
- NDUFS8 | c.183G>T p.W61C | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.593); catalogued as rs779081856, COSV50292090; called by muse, mutect2, varscan2
- NELL1 | c.1495G>A p.G499R | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV100124045; called by muse, mutect2, varscan2
- NRXN3 | c.2791G>A p.V931I (on ENST00000335750 / NM_001330195.2; = p.V558I on NM_004796.6) | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.952); catalogued as rs755514894, COSV59817552; called by muse, mutect2, varscan2
- NUDT22 | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.817); catalogued as rs750030208, COSV54176159; called by muse, varscan2
- NXF3 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 58/68 reads (85%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV67703300; called by muse, mutect2, varscan2
- OR10K1 | c.487G>A p.V163I | Missense Mutation (SNP) | VAF 56/128 reads (44%) | SIFT tolerated (0.55); PolyPhen benign (0.022); catalogued as COSV56874842; called by muse, mutect2, varscan2
- OR51G1 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.7); catalogued as COSV100429362, COSV58969134; called by muse, mutect2
- OR6N1 | c.410C>T p.T137I | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV58650808; called by muse, mutect2, varscan2
- OR7D4 | c.575C>T p.T192I | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.443); catalogued as COSV58072305; called by muse, mutect2, varscan2
- OTOF | c.4060G>A p.E1354K (on ENST00000272371 / NM_194248.3; = p.E587K on NM_004802.4) | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.152); catalogued as COSV55523530; called by muse, mutect2, varscan2
- OTOP2 | c.484G>A p.V162I | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.86); PolyPhen benign (0.038); catalogued as rs373104376; called by muse, mutect2, varscan2
- OTUD6A | c.612G>A p.M204I | Missense Mutation (SNP) | VAF 21/22 reads (95%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as rs776133793, COSV57973519; called by muse, mutect2, varscan2
- PCDHB14 | c.101C>T p.S34F | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.25); catalogued as rs1262522304, COSV53388645; called by muse, mutect2, varscan2
- PCLO | c.7823C>T p.S2608L | Missense Mutation (SNP) | VAF 50/194 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); catalogued as COSV61624551; called by muse, mutect2, varscan2
- PDCD1 | c.113C>T p.S38F | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs1243031095, COSV57690562; called by muse, mutect2
- PITX2 | c.616T>C p.S206P (on ENST00000354925 / NM_001204397.1; = p.S213P on NM_000325.6) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.916); catalogued as COSV60742545; called by muse, mutect2, varscan2
- PLOD2 | c.1609C>T p.P537S | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs1370785906, COSV99283170; called by muse, mutect2, varscan2
- PLXNA1 | c.4993C>T p.Q1665* | Nonsense Mutation (SNP) | VAF 22/62 reads (35%) | catalogued as COSV52533740; called by muse, mutect2, varscan2
- POSTN | c.326G>A p.G109E | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.909); catalogued as COSV65713531; called by muse, mutect2, varscan2
- PPP1R3A | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV52894772; called by muse, mutect2, varscan2
- PPP6C | c.171G>A p.Q57= | Splice Region (SNP) | VAF 67/170 reads (39%) | catalogued as rs1275605390, COSV65209472; called by muse, mutect2, varscan2
- PRAG1 | c.3895G>A p.G1299S | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1428551557, COSV100422685; called by muse, mutect2, varscan2
- PSG5 | c.1001C>T p.P334L | Missense Mutation (SNP) | VAF 61/153 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV61655602; called by muse, mutect2, varscan2
- PTPN5 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV62129158; called by muse, mutect2, varscan2
- PTPRT | c.4081G>A p.E1361K | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.3); catalogued as rs1417250081, COSV62030893; called by muse, mutect2, varscan2
- RAPGEF2 | c.1043C>T p.P348L | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as COSV52434721; called by muse, mutect2, varscan2
- RPGRIP1L | c.2842C>T p.P948S | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as rs1486116698, COSV50902825; called by muse, mutect2, varscan2
- SCN10A | c.2542G>A p.G848R | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV71862834; called by muse, mutect2, varscan2
- SCN9A | c.482G>A p.G161E | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57628037; called by muse, mutect2, varscan2
- SCP2D1 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.045); catalogued as COSV53859071; called by muse, mutect2, varscan2
- SDCCAG8 | c.352C>T p.L118F | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV59412746; called by muse, mutect2, varscan2
- SEMA5B | c.2114G>A p.G705D | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99532958; called by muse, mutect2, varscan2
- SEMA5B | c.2113G>A p.G705S | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1156482900, COSV99532961; called by muse, mutect2, varscan2
- SEPTIN4 | c.659G>A p.R220K | Missense Mutation (SNP) | VAF 65/124 reads (52%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.019); catalogued as COSV58729072; called by muse, mutect2, varscan2
- SLC1A7 | c.812G>A p.G271D | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65201689; called by muse, mutect2, varscan2
- SLCO1B3 | c.647G>A p.G216E | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as rs375847286; called by muse, mutect2, varscan2
- SLITRK1 | c.1172G>A p.R391Q | Missense Mutation (SNP) | VAF 111/201 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.138); catalogued as COSV65674545; called by muse, mutect2, varscan2
- SLITRK5 | c.1351C>T p.R451C | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs1414302227, COSV100281383, COSV61527288; called by muse, mutect2, varscan2
- SNCAIP | c.835C>T p.Q279* | Nonsense Mutation (SNP) | VAF 20/50 reads (40%) | catalogued as rs1213411485, COSV54423516; called by muse, mutect2, varscan2
- SPTA1 | c.170T>C p.V57A | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.34); PolyPhen benign (0.414); catalogued as COSV63761215; called by muse, mutect2, varscan2
- SSH1 | c.767A>C p.K256T | Missense Mutation (SNP) | VAF 78/161 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV58460909; called by muse, mutect2, varscan2
- STAG3 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 77/257 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.276); catalogued as rs140021945; called by muse, mutect2, varscan2
- TBX18 | c.1201C>T p.H401Y | Missense Mutation (SNP) | VAF 32/44 reads (73%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.993); catalogued as rs1234961449, COSV63736399; called by muse, mutect2, varscan2
- TBX4 | c.1321C>T p.P441S | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs1217962593, COSV53610321; called by muse, mutect2, varscan2
- TESK1 | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs1321524726, COSV52412650; called by muse, mutect2, varscan2
- TMA16 | c.499A>G p.I167V | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs776546045, COSV99922334; called by muse, mutect2, varscan2
- TRIM10 | c.1433C>T p.S478F | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.259); catalogued as rs538119524, COSV100939812; called by muse, mutect2, varscan2
- TRIM49 | c.57G>A p.M19I | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.214); catalogued as rs1248799832, COSV100316206; called by mutect2, varscan2
- TRIM67 | c.1861A>T p.I621F | Missense Mutation (SNP) | VAF 54/119 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV64160989; called by muse, mutect2, varscan2
- TRIML2 | c.898A>C p.T300P | Missense Mutation (SNP) | VAF 67/143 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as rs778131987, COSV58720398; called by muse, mutect2, varscan2
- TRPC5 | c.1600G>A p.G534R | Missense Mutation (SNP) | VAF 57/69 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99462382; called by muse, mutect2, varscan2
- TTN | c.102210A>T p.Q34070H (on ENST00000591111; = p.Q26646H on NM_003319.4) | Missense Mutation (SNP) | VAF 8/21 reads (38%) | PolyPhen probably damaging (0.997); catalogued as COSV60407169; called by muse, mutect2, varscan2
- TTN | c.93122G>A p.G31041E (on ENST00000591111; = p.G23617E on NM_003319.4) | Missense Mutation (SNP) | VAF 51/134 reads (38%) | PolyPhen probably damaging (1); catalogued as COSV60407202; called by muse, mutect2, varscan2
- TTN | c.12922C>T p.L4308F (on ENST00000591111; = p.L4262F on NM_003319.4) | Missense Mutation (SNP) | VAF 13/51 reads (25%) | catalogued as COSV59935196, COSV60407235; called by muse, mutect2, varscan2
- UHRF1BP1 | c.3706G>A p.G1236R | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.486); catalogued as rs368884128; called by muse, mutect2
- VGLL1 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 37/43 reads (86%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV65703992; called by muse, mutect2, varscan2
- VSTM2A | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs200451254, COSV56492709; called by muse, mutect2
- VWF | c.5336G>A p.R1779Q | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.99); PolyPhen benign (0.349); catalogued as rs760828829, CM163351, COSV54637417; called by muse, mutect2, varscan2
- ZFYVE9 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV55101777; called by muse, mutect2, varscan2
- ZNF318 | c.5408C>T p.P1803L | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.006); catalogued as COSV100546446; called by muse, mutect2, varscan2
- ZNF318 | c.5407C>T p.P1803S | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.121); catalogued as rs754087473, COSV100546448; called by muse, mutect2, varscan2
- ZNF467 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 51/82 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV100118072; called by muse, mutect2, varscan2
- ZNF527 | c.1078T>G p.C360G | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62236545; called by muse, mutect2, varscan2
- ZNF560 | c.2195G>A p.R732Q | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.117); catalogued as rs747315246, COSV56866069; called by muse, mutect2, varscan2
- ZNF91 | c.1970C>T p.P657L | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.622); catalogued as COSV100323352; called by muse, mutect2
- TADA2A | c.70C>A p.L24I | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- USP53 | c.2333dup p.N778Kfs*11 | Frame Shift Ins (INS) | VAF 14/30 reads (47%) | called by mutect2, pindel, varscan2
- ABI3 | c.969G>A p.K323= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs779153352, COSV56799277; called by muse, mutect2, varscan2
- ACSM5 | c.1320G>A p.E440= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as COSV59375533; called by muse, mutect2, varscan2
- AFF3 | c.3411C>T p.S1137= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as COSV57878190; called by muse, mutect2
- AHI1 | c.288C>T p.V96= | Silent (SNP) | VAF 84/110 reads (76%) | catalogued as COSV55637708; called by muse, mutect2, varscan2
- ANKRD12 | c.1836C>T p.F612= | Silent (SNP) | VAF 68/155 reads (44%) | catalogued as COSV50841027; called by muse, mutect2, varscan2
- ATP11A | c.498C>T p.F166= | Silent (SNP) | VAF 48/70 reads (69%) | catalogued as COSV52126823; called by muse, mutect2, varscan2
- CADPS2 | c.2253C>T p.L751= | Silent (SNP) | VAF 21/94 reads (22%) | catalogued as rs1210042946, COSV57371788; called by muse, mutect2, varscan2
- CCDC110 | c.2277C>T p.T759= | Silent (SNP) | VAF 28/58 reads (48%) | catalogued as rs1287151540, COSV56873889; called by muse, varscan2
- DCAF4L2 | c.996G>A p.V332= | Silent (SNP) | VAF 60/107 reads (56%) | catalogued as COSV60482029; called by muse, mutect2, varscan2
- DNAH9 | c.4146G>A p.R1382= | Silent (SNP) | VAF 12/21 reads (57%) | catalogued as rs1200136392, COSV52381530; called by muse, mutect2, varscan2
- ERC2 | c.1695G>A p.L565= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as COSV55671781; called by muse, mutect2, varscan2
- FCRL3 | c.1980G>A p.P660= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as rs370292899, COSV63843916; called by muse, mutect2, varscan2
- HPCAL1 | c.102C>T p.F34= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as rs1045519641, COSV57149910; called by muse, mutect2, varscan2
- IL4I1 | c.279G>A p.R93= | Silent (SNP) | VAF 27/48 reads (56%) | catalogued as COSV62012529; called by muse, mutect2, varscan2
- IL7R | c.543G>A p.V181= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV57414603; called by muse, mutect2, varscan2
- JADE3 | c.1515G>A p.Q505= | Silent (SNP) | VAF 25/29 reads (86%) | catalogued as rs1556373375, COSV54471464; called by muse, mutect2, varscan2
- KDM3B | c.4887C>T p.L1629= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV58696444; called by muse, mutect2, varscan2
- KDM4B | c.1530C>T p.P510= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs760719435, COSV50262478; called by muse, mutect2, varscan2
- KPRP | c.639C>T p.S213= | Silent (SNP) | VAF 52/117 reads (44%) | catalogued as COSV64223185; called by muse, mutect2, varscan2
- LARGE1 | c.1416G>A p.T472= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs755991003, COSV61674038; ClinVar: likely benign; called by muse, mutect2, varscan2
- LPA | c.3642G>A p.R1214= | Silent (SNP) | VAF 20/24 reads (83%) | catalogued as COSV60299060; called by muse, mutect2, varscan2
- MISP | c.1569C>T p.P523= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as rs766774963, COSV53122793; called by muse, mutect2, varscan2
- MTMR1 | c.240C>T p.S80= | Silent (SNP) | VAF 40/44 reads (91%) | catalogued as COSV100954062, COSV100954150; called by muse, mutect2, varscan2
- NCAM1 | c.696C>T p.T232= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as COSV57526903; called by muse, mutect2, varscan2
- NPHP4 | c.3183C>T p.V1061= | Silent (SNP) | VAF 7/10 reads (70%) | catalogued as rs1338238540, COSV65398677; called by muse, mutect2, varscan2
- OR2M4 | c.189C>T p.L63= | Silent (SNP) | VAF 52/116 reads (45%) | catalogued as rs1331840680, COSV60710029; called by muse, mutect2, varscan2
- OR5B3 | c.234C>T p.I78= | Silent (SNP) | VAF 48/110 reads (44%) | catalogued as rs762934435, COSV100512040, COSV58679008; called by muse, mutect2, varscan2
- OR7D4 | c.576C>T p.T192= | Silent (SNP) | VAF 25/72 reads (35%) | catalogued as COSV58073084; called by muse, mutect2, varscan2
- OTOF | c.4059G>A p.L1353= (on ENST00000272371 / NM_194248.3; = p.L586= on NM_004802.4) | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as rs775595020, COSV55523561; called by muse, mutect2, varscan2
- PDCD1 | c.114C>T p.S38= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as rs1202353836, COSV100545536; called by muse, mutect2
- POTEF | c.2022G>A p.K674= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as rs761759443, COSV100665247, COSV62539689; called by muse, mutect2, varscan2
- PPARGC1A | c.1176C>T p.S392= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as COSV53534601; called by muse, mutect2, varscan2
- PTCHD3 | c.1368C>T p.V456= | Silent (SNP) | VAF 22/24 reads (92%) | catalogued as rs771956313, COSV71257272; called by muse, mutect2
- RYR3 | c.5556G>A p.L1852= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs1432536910, COSV66778682; called by muse, mutect2, varscan2
- SCN9A | c.3660G>A p.K1220= (on ENST00000303354; = p.K1209= on NM_002977.3) | Silent (SNP) | VAF 14/23 reads (61%) | catalogued as COSV57628018; called by muse, mutect2, varscan2
- SH2D7 | c.759G>A p.R253= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV51948577; called by muse, mutect2, varscan2
- SIGLEC5 | c.1023C>T p.S341= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV55784764; called by muse, mutect2, varscan2
- SLITRK1 | c.1968C>T p.S656= | Silent (SNP) | VAF 26/49 reads (53%) | catalogued as COSV65674547, COSV65678084; called by muse, mutect2, varscan2
- SNX15 | c.420C>T p.I140= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as COSV57248908; called by muse, mutect2, varscan2
- ST7 | c.666C>T p.P222= | Silent (SNP) | VAF 15/95 reads (16%) | catalogued as COSV99622785; called by muse, mutect2, varscan2
- ST7 | c.667C>T p.L223= | Silent (SNP) | VAF 16/95 reads (17%) | catalogued as COSV55394476; called by muse, mutect2, varscan2
- SYTL4 | c.1533C>T p.T511= | Silent (SNP) | VAF 25/26 reads (96%) | catalogued as rs1441042982, COSV52172582; called by muse, mutect2, varscan2
- TBCCD1 | c.1284C>T p.D428= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as COSV100112109; called by muse, mutect2, varscan2
- TENT4A | c.1581C>T p.A527= | Silent (SNP) | VAF 43/142 reads (30%) | catalogued as rs1439984715, COSV50094852; called by muse, mutect2, varscan2
- TLE2 | c.1689C>T p.F563= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV53583811; called by muse, mutect2, varscan2
- TRAV20 | c.93C>T p.A31= | Silent (SNP) | VAF 21/46 reads (46%) | called by muse, mutect2, varscan2
- USP36 | c.516C>T p.N172= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV100361755; called by muse, mutect2, varscan2
- CFAP57 | c.1929+71C>T | Intron (SNP) | VAF 26/87 reads (30%) | catalogued as COSV65266185; called by muse, mutect2, varscan2
- FYB1 | c.1907+1669G>A | Intron (SNP) | VAF 25/66 reads (38%) | catalogued as COSV60957733; called by muse, mutect2, varscan2
- SNORD3B-2 | n.153G>A | RNA (SNP) | VAF 51/311 reads (16%) | catalogued as rs746102763; called by muse, varscan2
- VN1R10P | n.651G>A | RNA (SNP) | VAF 76/196 reads (39%) | called by muse, mutect2, varscan2
- ZNF658B | n.2240C>T | RNA (SNP) | VAF 120/367 reads (33%) | called by muse, mutect2, varscan2
- ZNF658B | n.2004C>T | RNA (SNP) | VAF 144/328 reads (44%) | catalogued as rs1324397783; called by muse, mutect2
